Gene-level copy-number profile of tumor specimen TCGA-OR-A5JV-01A from TCGA case TCGA-OR-A5JV, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 55.6 years (20,319 days).
Specimen TCGA-OR-A5JV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.d4ee0ec3-7a9c-4f8d-80a8-c3a758916f01.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5JV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a7007f37-1348-4748-84f3-d286023474db

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 2,160; copy number 2: 50; copy number 3: 29,978; copy number 4: 10,038; copy number 5: 414; copy number 6: 17,094; copy number 7: 1; copy number 8: 72.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5JV-01A-11D-A29H-01): tumor purity 0.46, ploidy 2.79, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,064,089–181,159,149, 1 gene: LINC00290.
- chr11:85,452,282–85,811,159, 7 genes: AP003035.1, RNU6-1292P, TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 73 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–2,555,694, 72 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr9:9,442,060–9,442,380, 1 gene, copy number 7: RN7SL5P.

Autosomal genes at a single copy (total copy number 1): 2,160. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
